TCGA case TCGA-AN-A04A — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e5aae05a-478e-4a55-a27c-12b2b4be302a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 36.8 years (13,445 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Lower Inner / Breast, Left Lower Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 7; Micrometastasis present: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Treatment anatomic sites: Breast.

Follow-up (1 entry)
- Days to follow up: 90 days; Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 0.
- ESR1 (IHC): Positive; Staining intensity value: 2+.
- PGR (IHC): Positive; Staining intensity value: 1+.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Perimenopausal.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AN-A04A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-AN-A04A-01A-02-BS2: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 23; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide TCGA-AN-A04A-01A-01-BS1: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 2; Percent stromal cells: 16; Percent lymphocyte infiltration: 13; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-AN-A04A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Er positivity method: Allred (Biocare); Pr positivity define method: Allred (Biocare); Axillary staging method: No axillary staging; Surgical procedure first: Simple Mastectomy; Surgery for positive margins: Modified radical mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Peri (6-12 months since last menstrual period); Micromet detection by IHC: No; Er IHC score: 2+; Her2 IHC score: 0; Method initial path diagnosis: Tumor resection; Lymph nodes examined IHC count: 0; Pr positivity scale other: 87; Er positivity scale other: 112; Her2 positivity scale other: 0; Her2 positivity method text: Dako Hercept test; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Lower Inner Quadrant; Anatomic organ subdivision: Left Lower Outer Quadrant.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 90 days; disease-specific survival: no event (censored), 90 days; progression-free interval: no event (censored), 90 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AN-A04A-01A-21D-A036-01): tumor purity 0.56, ploidy 3, whole-genome doublings 1.
